Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8590, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8590-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

	Case ID	Gross Description

[page 2 of 5]
Microscopic Description	Diagnosis Details

[page 3 of 5]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 8 x 7 x 1.5 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Lesser and greater omentum Lymph nodes: 5/7 positive for metastasis (Intraabdominal 5/7) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 4 of 5]
ID

ID

[page 5 of 5]
Excision date

Source: NCI Genomic Data Commons file 9aed8ef7-da51-4102-9ba5-3b2385e00de6 (TCGA-BR-8590.B7F40CBC-844D-4F3E-92C1-187C4DCCE179.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).